Somatic mutation profile of tumor specimen TCGA-HZ-A77Q-01A (aliquot TCGA-HZ-A77Q-01A-11D-A36O-08) from TCGA case TCGA-HZ-A77Q, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 55.8 years (20,366 days).
Specimen TCGA-HZ-A77Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fcf6808-70df-4f47-acf9-90d267c2abf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A77Q-10A (Blood Derived Normal), aliquot TCGA-HZ-A77Q-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92eaafac-0137-44c4-9625-57b26335c5c0

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 34, Silent 11, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 26/406 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- SMAD4 | c.1072_1080del p.G358_D360del | In Frame Del (DEL) | VAF 36/320 reads (11%) | hotspot (GDC flag); called by mutect2, pindel
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 46/255 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMPH | c.1158G>A p.T386= | Splice Region (SNP) | VAF 61/544 reads (11%) | catalogued as rs754663057, COSV57737194; called by muse, mutect2, varscan2
- ANXA11 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as COSV55415183, COSV99627614; called by muse, mutect2
- ASB15 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 80/671 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781763479, COSV51924530; called by muse, mutect2, varscan2
- BARHL1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV99707753; called by muse, mutect2
- BNC1 | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 93/1093 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV100597545; called by muse, mutect2
- CHPF2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as COSV99223403; called by muse, mutect2, varscan2
- COL4A2 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100847522; called by muse, mutect2, varscan2
- EBAG9 | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV100520756, COSV100520921; called by muse, mutect2, varscan2
- EDA2R | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs779772710, COSV53631864, COSV99491060; called by muse, mutect2
- FAM53A | c.797G>C p.S266T | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.15); catalogued as COSV100357330; called by muse, mutect2, varscan2
- FBN2 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs371826887, COSV52494753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXP3 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs782303740, COSV66051448; called by muse, mutect2
- GATA2 | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV100351605; called by muse, mutect2
- GRM4 | c.2287C>T p.L763F | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100946959; called by muse, mutect2, varscan2
- HECW2 | c.3956T>C p.I1319T | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV99649361; called by muse, mutect2, varscan2
- HUNK | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99529052; called by muse, mutect2
- IKZF1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 19/152 reads (13%) | catalogued as COSV58787350; called by muse, mutect2, varscan2
- KRT33B | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52440159; called by muse, mutect2
- MAP2K4 | c.685+1G>T p.X229_splice | Splice Site (SNP) | VAF 51/516 reads (10%) | catalogued as COSV100796574, COSV62255339; called by muse, mutect2, varscan2
- MFN1 | c.753+1G>A p.X251_splice | Splice Site (SNP) | VAF 31/248 reads (13%) | catalogued as rs1336070880, COSV99764762; called by muse, mutect2, varscan2
- MRPS36 | c.261A>T p.K87N | Missense Mutation (SNP) | VAF 70/629 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99841132; called by muse, mutect2, varscan2
- NRXN3 | c.3079C>T p.R1027C (on ENST00000335750 / NM_001330195.2; = p.R654C on NM_004796.6) | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140301017; called by muse, mutect2, varscan2
- OCA2 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1390458631, COSV62355676; called by muse, mutect2, varscan2
- POU4F2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV55587359; called by muse, mutect2
- PTPRA | c.2136C>G p.I712M | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV99400807; called by muse, mutect2, varscan2
- PTPRN | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 37/286 reads (13%) | catalogued as COSV99834447; called by muse, mutect2, varscan2
- SDR42E1 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 32/578 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs780258256, COSV100200811; called by muse, mutect2
- SH2D5 | c.737G>A p.R246H (on ENST00000444387 / NM_001103161.2; = p.R162H on NM_001103160.2) | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs761752861, COSV66706683; called by muse, mutect2, varscan2
- SLC26A7 | c.1218+1G>C p.X406_splice | Splice Site (SNP) | VAF 83/813 reads (10%) | catalogued as COSV99404552; called by muse, mutect2, varscan2
- SRCIN1 | c.2728G>A p.G910R (on ENST00000621492; = p.G876R on NM_025248.3) | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs533940451; called by muse, mutect2, varscan2
- SSTR5 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs769578728, COSV99559941; called by muse, mutect2, varscan2
- TEKT4 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs112344899; called by muse, mutect2, varscan2
- TPO | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375314609; called by muse, mutect2, varscan2
- TRIM42 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1235611090, COSV53882258; called by muse, mutect2
- TRPS1 | c.3827dup p.N1276Kfs*5 (on ENST00000220888 / NM_001330599.2; = p.N1289Kfs*5 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 74/626 reads (12%) | catalogued as rs1401148397; called by mutect2, varscan2
- USP37 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 92/603 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV99294965; called by muse, mutect2, varscan2
- XCR1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183698296, COSV58569784; called by muse, mutect2
- ZFHX4 | c.7132G>T p.A2378S | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV50664975; called by muse, mutect2, varscan2
- CLEC18B | c.1259T>A p.L420Q | Missense Mutation (SNP) | VAF 29/540 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PCLO | c.6346_6347del p.L2116Yfs*15 | Frame Shift Del (DEL) | VAF 20/201 reads (10%) | called by pindel, varscan2
- RNF43 | c.612del p.V205Wfs*7 | Frame Shift Del (DEL) | VAF 39/353 reads (11%) | called by mutect2, pindel, varscan2
- BTN1A1 | c.142C>T p.L48= | Silent (SNP) | VAF 14/331 reads (4%) | catalogued as COSV99764607; called by muse, mutect2
- CACNA1S | c.4236G>A p.E1412= | Silent (SNP) | VAF 24/262 reads (9%) | catalogued as COSV62943377; called by muse, mutect2
- GABRA2 | c.786C>A p.I262= | Silent (SNP) | VAF 55/459 reads (12%) | catalogued as COSV100734827, COSV62911492; called by muse, mutect2, varscan2
- KRT24 | c.705G>A p.E235= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as COSV99232204; called by muse, mutect2, varscan2
- MORC2 | c.2442C>T p.A814= (on ENST00000397641 / NM_001303256.3; = p.A752= on NM_014941.3) | Silent (SNP) | VAF 177/945 reads (19%) | catalogued as rs757728179, COSV99310478; called by muse, mutect2, varscan2
- PCP4 | c.129G>A p.A43= | Silent (SNP) | VAF 32/389 reads (8%) | catalogued as rs769109934, COSV60786391, COSV60788080; called by muse, mutect2
- RNF213 | c.11862A>G p.L3954= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as COSV100301678; called by muse, mutect2
- RTN2 | c.600C>T p.P200= | Silent (SNP) | VAF 32/239 reads (13%) | catalogued as rs886386424, COSV55593332; called by muse, mutect2, varscan2
- SHROOM2 | c.2382T>C p.F794= | Silent (SNP) | VAF 41/294 reads (14%) | catalogued as COSV101099160, COSV66605887; called by muse, mutect2, varscan2
- TRIM42 | c.525G>A p.K175= | Silent (SNP) | VAF 45/420 reads (11%) | catalogued as rs574747515, COSV99648948; called by muse, mutect2, varscan2
- TTLL6 | c.1959G>A p.S653= (on ENST00000393382 / NM_001130918.3; = p.S346= on NM_173623.3) | Silent (SNP) | VAF 78/521 reads (15%) | catalogued as rs763876040, COSV64977426; called by muse, mutect2, varscan2
